RC case RC-B6E6 — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Lymph nodes. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2c7bba57-1c50-4044-a826-7f2c8c4ed076

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1965; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Peripheral T-cell lymphoma, NOS: ICD-O-3 morphology code: 9702/3; ICD-10 code: C84; Tissue or organ of origin: Lymph node, NOS; Site of resection or biopsy: Lymph nodes of axilla or arm; Classification of tumor: primary; Age at diagnosis: 56.8 years (20,761 days); Year of diagnosis: 2022; Method of diagnosis: Excisional Biopsy; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Ann arbor b symptoms described array: Fever; Ann Arbor extranodal involvement: No; International Prognostic Index (IPI): High Risk; Sites of involvement: Lymph Node, Axillary / Lymph Node, Iliac-Common / Lymph Node, Iliac-External / Lymph Node, Inguinal / Lung, NOS.
   Pathology details: Bone marrow malignant cells: Yes; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Etoposide + Prednisone + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: CHOPE; Days to treatment start: 20 days; Number of cycles: 4; Treatment outcome: Treatment Ongoing; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Treatment Ongoing; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; adjuvant Radiation Therapy, NOS, postoperative; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.

Follow-up (3 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 40.
- Day 107 (end of treatment course 1): Disease response: Partial Response.
- Follow-up contact recording only the day: day 109.

Molecular and laboratory tests
- Lactate Dehydrogenase 247 U/L [Blood test normal range upper: 220].
- Epstein-Barr Virus (ISH): Negative.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Skin Rash / Syphilis.
- Timepoint category: Prior to Diagnosis; Comorbidities: Psoriasis / Erythroderma / Pulmonary Fibrosis / Eczema / Syphilis / Cardiomyopathy.
- Timepoint category: Initial Diagnosis; Weight: 86.8 kg.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample RC-B6E6-NB1-A: Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample RC-B6E6-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide RC-B6E6-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 2.
